Somatic mutation profile of tumor specimen TCGA-28-5220-01A (aliquot TCGA-28-5220-01A-01D-1486-08) from TCGA case TCGA-28-5220, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.4 years (24,622 days).
Specimen TCGA-28-5220-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4efe72bc-0ad6-41ef-886e-7fe838f092cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5220-10A (Blood Derived Normal), aliquot TCGA-28-5220-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e9d3a4f-b9dd-4d02-94e5-d57ad695fed6

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 7, Frame Shift Ins 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP5 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1486425523, COSV70470109; called by muse, mutect2, varscan2
- ENC1 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs758578453, COSV56630787; called by muse, mutect2, varscan2
- EXOC7 | c.1433A>C p.D478A (on ENST00000335146 / NM_001145297.4; = p.D396A on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV58744250; called by muse, mutect2, varscan2
- KASH5 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs568170851, COSV71358352; called by muse, mutect2
- KRT20 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as rs1322970219, COSV51424721; called by muse, mutect2, varscan2
- LYN | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 243/517 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV70206277; called by muse, mutect2, varscan2
- MROH2B | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.029); catalogued as rs754152435, COSV68188160; called by muse, mutect2, varscan2
- OR51M1 | c.188C>A p.T63N | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as COSV60785247; called by muse, mutect2
- PDE11A | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV53705257; called by muse, mutect2, varscan2
- PDGFRB | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758280032, COSV55805130; called by muse, mutect2, varscan2
- PFDN4 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); catalogued as COSV65063604; called by muse, mutect2, varscan2
- PKD1L1 | c.8059C>T p.P2687S | Missense Mutation (SNP) | VAF 123/421 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.098); catalogued as rs141837186; called by muse, mutect2, varscan2
- PTCHD3 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as rs200246680, COSV71257210; called by muse, mutect2, varscan2
- RABGGTA | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs756007491, COSV53771393; called by muse, mutect2, varscan2
- RBM19 | c.2681T>C p.L894P | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55697020; called by muse, mutect2, varscan2
- RELN | c.6146C>T p.A2049V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as rs374232523; called by muse, mutect2, varscan2
- RIBC2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs137932273, COSV61582130; called by muse, mutect2, varscan2
- RNF32 | c.641C>G p.P214R | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58734333; called by muse, mutect2, varscan2
- SDK1 | c.1746C>A p.D582E | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV67384399; called by muse, mutect2, varscan2
- SLC35G3 | c.405A>T p.K135N | Missense Mutation (SNP) | VAF 165/376 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52012386; called by muse, mutect2, varscan2
- SMC1A | c.1913C>A p.T638K | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV59131317; called by muse, mutect2, varscan2
- SPHKAP | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 386/894 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs754224869, COSV60884372; called by muse, mutect2, varscan2
- TBKBP1 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV64654326; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1426047047, COSV51515143; called by muse, mutect2, varscan2
- TRPM2 | c.446C>G p.T149R | Missense Mutation (SNP) | VAF 75/218 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55967962, COSV55975287; called by muse, mutect2, varscan2
- ZNF407 | c.5983G>A p.A1995T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55265915; called by muse, mutect2, varscan2
- GALNT5 | c.87dup p.M30Hfs*10 | Frame Shift Ins (INS) | VAF 99/308 reads (32%) | called by mutect2, pindel, varscan2
- THAP10 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- TRAM1 | c.310-10_324del p.X104_splice | Splice Site (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel
- ZNF101 | c.450dup p.I151Hfs*5 | Frame Shift Ins (INS) | VAF 79/295 reads (27%) | called by mutect2, pindel, varscan2
- COL14A1 | c.1128C>T p.A376= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as COSV52864879; called by muse, mutect2, varscan2
- CORO7 | c.1170G>A p.R390= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV52033200; called by muse, mutect2
- OR6X1 | c.591C>T p.G197= | Silent (SNP) | VAF 28/274 reads (10%) | catalogued as rs776817105, COSV60009396; called by muse, mutect2
- PICK1 | c.1170G>A p.T390= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs1245280642, COSV57634837; called by muse, varscan2
- SLC2A1 | c.174C>T p.P58= | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as rs757768500, COSV65288124; called by muse, mutect2, varscan2
- TBC1D17 | c.1299C>T p.N433= | Silent (SNP) | VAF 108/252 reads (43%) | catalogued as rs201269112, COSV55580573; called by muse, mutect2, varscan2
- TGM2 | c.150C>T p.Y50= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as rs372553139, COSV63932196; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503128 T>C | 5'Flank (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
